Somatic mutation profile of tumor specimen TCGA-XE-A8H1-01A (aliquot TCGA-XE-A8H1-01A-11D-A435-10) from TCGA case TCGA-XE-A8H1, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 24.3 years (8,893 days).
Specimen TCGA-XE-A8H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c400906-670d-4f30-8c3d-5f81470c8682.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XE-A8H1-10A (Blood Derived Normal), aliquot TCGA-XE-A8H1-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69ca13ff-0bd9-4f13-b212-24969eb784d1

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCAF8L2 | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV70547957; called by muse, mutect2, varscan2
- MMACHC | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV53115194; called by muse, mutect2, varscan2
- WDFY1 | c.104A>G p.K35R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1389554403; called by muse, varscan2
- NECTIN3 | c.496G>C p.V166L | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- SPHK2 | c.891C>A p.G297= | Silent (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- UBE2G2 | c.-21C>G | 5'UTR (SNP) | VAF 4/16 reads (25%) | catalogued as rs1171128812; called by mutect2, varscan2
